Somatic mutation profile of tumor specimen 1b2ab076-c72f-4bbe-b9f9-657d24 (aliquot 1b2ab076-c72f-4bbe-b9f9-657d24_D6) from CPTAC case 04OV041, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 1b2ab076-c72f-4bbe-b9f9-657d24: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cac0bc98-5bd9-4608-8714-86047c93d730.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 244351b1-dec2-40ef-aa8c-118072 (Blood Derived Normal), aliquot 244351b1-dec2-40ef-aa8c-118072_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4cf60f4-0266-442e-9523-16a3ccd11bfb

The open-access MAF lists 101 somatic variants for this specimen: 66 protein-altering or splice-affecting, 21 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 21, Intron 6, 3'UTR 4, RNA 3, Splice Region 3, Nonsense Mutation 2, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 152/315 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP24 | c.2200G>T p.V734L (on ENST00000395184 / NM_001025616.3; = p.V641L on NM_031305.3) | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as COSV99981842; called by muse, mutect2, varscan2
- ATP5IF1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV55282827; called by muse, mutect2, varscan2
- ATRX | c.6362C>G p.S2121C | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64879276; called by muse, mutect2
- ATRX | c.3100del p.Q1034Kfs*16 | Frame Shift Del (DEL) | VAF 23/183 reads (13%) | catalogued as COSV64870622; called by mutect2, pindel, varscan2
- BCORL1 | c.4860C>G p.C1620W | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99498873; called by muse, mutect2
- C16orf82 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs770685890; called by muse, mutect2, varscan2
- CHEK2 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.011); catalogued as COSV60420569; called by muse, mutect2, varscan2
- CLIC6 | c.1069G>C p.D357H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1309434223; called by muse, mutect2
- CNTN5 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs752165707, COSV54306589; called by muse, mutect2, varscan2
- COL4A6 | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.202); catalogued as COSV57866322; called by muse, mutect2
- CSMD3 | c.4088G>A p.G1363E (on ENST00000297405 / NM_001363185.1; = p.G1259E on NM_052900.3) | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1211285238; called by muse, mutect2, varscan2
- FGFR2 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs755453106; called by muse, mutect2, varscan2
- FOSL2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1007176760, COSV53104155; called by muse, mutect2, varscan2
- JRKL | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 35/139 reads (25%) | catalogued as COSV99567641; called by muse, mutect2, varscan2
- KALRN | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs749891135, COSV53755839; called by muse, mutect2
- MAGEA8 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs143187496, COSV54063868; called by muse, mutect2
- NBAS | c.2048G>T p.R683L | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774711181, COSV55733772; called by muse, mutect2
- NSUN3 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs544261710, COSV58937204; called by muse, mutect2, varscan2
- OR5B17 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as rs142474037; called by muse, mutect2, varscan2
- POTED | c.177C>A p.S59R | Missense Mutation (SNP) | VAF 21/541 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.307); catalogued as COSV55047731; called by muse, mutect2
- RAB39A | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as rs755856456, COSV57694800; called by muse, mutect2, varscan2
- RBM10 | c.2705G>A p.R902Q | Missense Mutation (SNP) | VAF 41/956 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs190398066; called by muse, mutect2
- RIMS1 | c.4712C>G p.S1571C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53443887; called by muse, mutect2, varscan2
- SH3RF2 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs566012144, COSV63038623; called by muse, mutect2, varscan2
- TENM1 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs890534757; called by muse, mutect2, varscan2
- THSD7B | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs868302831, COSV55733062; called by muse, mutect2, varscan2
- TTN | c.66286G>A p.D22096N (on ENST00000591111; = p.D14672N on NM_003319.4) | Missense Mutation (SNP) | VAF 84/333 reads (25%) | PolyPhen possibly damaging (0.714); catalogued as rs758836824; called by muse, mutect2, varscan2
- ZNF862 | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs765311603; called by muse, mutect2, varscan2
- AL117348.2 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 23/399 reads (6%) | PolyPhen benign (0); called by muse, mutect2
- ATP2B3 | c.915A>G p.K305= | Splice Region (SNP) | VAF 16/130 reads (12%) | called by mutect2, varscan2
- BAIAP2L1 | c.1228G>C p.V410L | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BLVRA | c.353-8C>T | Splice Region (SNP) | VAF 66/311 reads (21%) | called by muse, mutect2, varscan2
- C12orf43 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CD101 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- CNTNAP3 | c.3614C>A p.A1205E | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2
- DOCK11 | c.3784A>T p.S1262C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EMP3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FBN2 | c.7725T>G p.C2575W | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR22 | c.460A>T p.M154L | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GRHL2 | c.1052C>A p.A351E | Missense Mutation (SNP) | VAF 116/380 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HELZ | c.3071A>G p.D1024G | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- IGSF10 | c.4010A>G p.E1337G | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INSR | c.2359A>T p.S787C | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2
- ITLN2 | c.625G>C p.G209R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- KAZN | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2
- LRRIQ1 | c.4097C>T p.T1366I | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRN4 | c.1493A>C p.Q498P | Missense Mutation (SNP) | VAF 87/397 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- MAGED1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MAGED1 | c.2292C>A p.N764K | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); called by muse, mutect2
- MCTP2 | c.1760T>C p.L587P | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MPRIP | c.2393_2400dup p.D801Sfs*68 | Frame Shift Ins (INS) | VAF 15/122 reads (12%) | called by mutect2, varscan2
- MRPL1 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MTG1 | c.823A>G p.K275E | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MTMR1 | c.606A>C p.K202N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYO3A | c.2102A>T p.D701V | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by mutect2, varscan2
- MYOM3 | c.3332G>T p.R1111I | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- NRAP | c.4994_5011del p.V1665_P1670del (on ENST00000359988 / NM_001322945.2; = p.V1630_P1635del on NM_006175.4) | In Frame Del (DEL) | VAF 29/143 reads (20%) | called by mutect2, pindel, varscan2
- NTSR1 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.046); called by muse, varscan2
- P2RX2 | c.520G>C p.G174R (on ENST00000343948 / NM_170683.4; = p.G102R on NM_012226.5) | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- PALLD | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); called by muse, mutect2
- PITPNM1 | c.2745C>T p.N915= | Splice Region (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2
- RANBP2 | c.5025A>T p.L1675F | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPRY3 | c.797C>A p.T266N | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TBX5 | c.1227C>G p.S409R | Missense Mutation (SNP) | VAF 265/681 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ZNF831 | c.866G>C p.G289A | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ARMCX2 | c.870G>A p.R290= | Silent (SNP) | VAF 43/291 reads (15%) | called by muse, mutect2, varscan2
- ASAP3 | c.1398C>T p.G466= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as rs528515180; called by muse, mutect2, varscan2
- CCDC120 | c.1824G>T p.A608= | Silent (SNP) | VAF 123/252 reads (49%) | called by muse, mutect2, varscan2
- CLIC6 | c.1068G>A p.E356= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- CLNK | c.762G>T p.V254= | Silent (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- DMRTA1 | c.651T>C p.Y217= | Silent (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- GZMH | c.30T>C p.F10= | Silent (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- HECTD3 | c.619C>T p.L207= | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as rs1197527690; called by muse, mutect2, varscan2
- HNRNPCL1 | c.99G>A p.V33= | Silent (SNP) | VAF 28/129 reads (22%) | called by muse, mutect2, varscan2
- ITGB7 | c.342C>T p.G114= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs980559517; called by muse, mutect2, varscan2
- ITIH5 | c.1617C>A p.I539= | Silent (SNP) | VAF 21/301 reads (7%) | catalogued as COSV53671500; called by muse, mutect2
- KRTAP24-1 | c.165C>A p.L55= | Silent (SNP) | VAF 190/468 reads (41%) | called by muse, mutect2, varscan2
- MYH3 | c.9T>C p.S3= | Silent (SNP) | VAF 94/410 reads (23%) | called by muse, mutect2, varscan2
- NIF3L1 | c.693T>G p.L231= (on ENST00000409020 / NM_001369444.1; = p.L204= on NM_021824.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- NLRP5 | c.879G>A p.S293= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as rs1351524574, COSV66762258; called by muse, mutect2
- PRSS53 | c.99C>T p.P33= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs750018444; called by muse, mutect2, varscan2
- PSD2 | c.1644G>C p.G548= | Silent (SNP) | VAF 49/102 reads (48%) | called by muse, mutect2, varscan2
- SHANK3 | c.400C>T p.L134= | Silent (SNP) | VAF 35/168 reads (21%) | catalogued as rs779618882; called by muse, mutect2, varscan2
- SLC31A1 | c.471C>T p.N157= | Silent (SNP) | VAF 116/844 reads (14%) | catalogued as rs369107456; called by muse, mutect2, varscan2
- TMEM178A | c.36C>G p.L12= | Silent (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- WDFY4 | c.4266G>A p.A1422= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs1011412285; called by muse, mutect2, varscan2
- AC133561.1 | n.1564A>T | RNA (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- ACTG1 | c.*95A>T | 3'UTR (SNP) | VAF 28/265 reads (11%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+4147T>A | Intron (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- C2orf83 | n.445G>C | RNA (SNP) | VAF 17/243 reads (7%) | called by muse, mutect2
- DDX41 | c.*314G>A | 3'UTR (SNP) | VAF 33/203 reads (16%) | catalogued as COSV57251759; called by muse, mutect2, varscan2
- IGFN1 | c.1241+1200A>C | Intron (SNP) | VAF 17/169 reads (10%) | called by muse, mutect2, varscan2
- ILF3 | c.*1G>A | 3'UTR (SNP) | VAF 14/118 reads (12%) | catalogued as COSV99140415; called by mutect2, varscan2
- ITIH5 | c.2032+16C>T | Intron (SNP) | VAF 15/166 reads (9%) | catalogued as rs369903880; called by muse, mutect2
- KRTAP21-1 | c.*20C>G | 3'UTR (SNP) | VAF 48/379 reads (13%) | catalogued as rs1234307458; called by muse, mutect2, varscan2
- LILRB5 | c.1306+25C>T | Intron (SNP) | VAF 12/53 reads (23%) | catalogued as rs551870057; called by muse, mutect2, varscan2
- LINC01583 | n.1385G>C | RNA (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- MMP16 | c.1222+5184C>A | Intron (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- WLS | c.106+369G>A | Intron (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- ZNF284 | c.-27T>C | 5'UTR (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
